FM case AD5529 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Cervix uteri.
https://portal.gdc.cancer.gov/cases/6c0ccd88-b96f-45fa-a62f-2e88ad97c61d

Female, 27.4 years: Neuroendocrine carcinoma, NOS (ICD-O-3 8246/3) of the cervix uteri; metastasis biopsied or resected from the ovary. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Metastatic.
